Gene-level copy-number profile of tumor specimen TCGA-X6-A7WD-01A from TCGA case TCGA-X6-A7WD, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 63.9 years (23,341 days).
Specimen TCGA-X6-A7WD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a5352888-9ed9-4264-ae02-a1ad3e3b20f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A7WD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/264273bd-1757-44f4-856b-863fda8a27a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 206; copy number 2: 8,238; copy number 3: 7,216; copy number 4: 42,167; copy number 5: 256; copy number 6: 905; copy number 7: 205; copy number 10: 16; copy number 15: 534.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A7WD-01A-21D-A350-01): tumor purity 0.87, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:234,222,838–234,224,514, 1 gene: AC122134.1.
- chr10:87,751,512–88,584,530, 11 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr10:89,063,335–89,701,274, 21 genes: MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4.
- chr10:123,356,450–123,537,767, 2 genes (within-gene range 0–4): LINC02641, AL160290.1.
- chr10:130,131,770–131,311,721, 9 genes: PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, AC016816.1, MIR378C, TCERG1L, TCERG1L-AS1.
- chr13:49,956,670–50,125,720, 1 gene (within-gene range 0–2): DLEU2.
- chr13:50,044,649–50,906,856, 17 genes (within-gene range 0–2): AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7.
- chr17:7,661,779–7,833,744, 5 genes (within-gene range 0–15): TP53, WRAP53, EFNB3, DNAH2, RPL29P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 550 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:7,839,904–22,530,609, 550 genes, copy number 10–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
